Surgical pathology report (de-identified scan), TCGA case TCGA-06-0209, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0209-01A (Primary Tumor).

[page 1 of 2]
TCGA-06-0209

PATHOLOGICAL DIAGNOSIS:

- A. BRAIN, TEMPORAL LOBE, EXCISIONAL BIOPSY: MALIGNANT GLIOMA WITH NECROSIS.
B. BRAIN, TEMPORAL LOBE, EXCISIONAL BIOPSIES: GLIOBLASTOMA MULTIFORME. SEE MICROSCOPIC AND COMMENT.

ADDENDUM DIAGNOSIS:

- C. BRAIN, TEMPORAL LOBE, EXCISIONAL BIOPSIES: GLIOBLASTOMA MULTIFORME.
MIB-1 LABELLING INDEX 10%.
SEE ADDENDUM MICROSCOPIC.

Operation/Specimen: Brain tumor - past history of prostate.

Clinical History and Pre-Op Dx: [REDACTED] with very vascular temporal lobe lesion. Past history of prostate cancer in [REDACTED]

GROSS PATHOLOGY:

- A.
SPECIMEN: Brain tumor.
FIXATIVE: None.
GENERAL: Single, pink-yellow tissue fragments 0.4 x 0.3 x 0.2 cm.

INTRAOPERATIVE CONSULTATION, Smears and frozen section diagnoses:
Brain, temporal lobe biopsy: Necrotic vascular lesion with atypical cells, suspicious for glioma?. [REDACTED]

SECTIONS: 1, all submitted.

- B.
SPECIMEN: Brain tumor.
FIXATIVE: None.
GENERAL: Four pieces, 0.7 to 1.0 cm. in maximum dimension. Soft to firm, pink to red.

INTRAOPERATIVE CONSULTATION, Smears and frozen section diagnoses:
Brain, temporal lobe biopsy: Glioblastoma multiforme [REDACTED]

SECTIONS: 2 frozen section remnant; 3&4 - rest of the tumor.

- C.
SPECIMEN: Left temporal brain tumor.
FIXATIVE: Formalin.
GENERAL: Multiple fragments of variegated pale tan to dark red tumor, [REDACTED]

[page 2 of 2]
[REDACTED]
ranging in size from 0.3 to 1.7 cm.

SECTIONS: 5-8, all submitted.
[REDACTED]

TCGA-06-0209

MICROSCOPIC: A. Portions of a neoplasm with extensive areas of necrosis, a delicate vascular network and extensive cautery artifact. The neoplasm is moderately cellular, and its nuclei are pleomorphic and hyperchromatic. The necrosis and artifact prevent accurate evaluation of the tumor.

B. Portions of brain extensively infiltrated by an anaplastic glial neoplasm with extensive areas of necrosis associated with pseudopallisading. Mitotic figures are observed. Focally, there are frequent gemistocytes and perivascular lymphocytic infiltrate. The tumor has prominent microvessels, however, microvascular cellular proliferation is not prominent. There is vascular thrombosis.

COMMENT: The lesion is a glioblastoma multiforme. The current lesion may have evolved from a gemistocytic astrocytoma.

A MIB-1 labelling index will be performed, and an addendum report will follow.
[REDACTED]

ADDENDUM MICROSCOPIC:

C. Microscopy sections contain portions of brain with a glial neoplasm similar to that described for part B.

Immunoperoxidase stain with the MIB-1 antiserum performed on block #4, yields a labelling index of about 10% in the more active areas.
[REDACTED]
[REDACTED]

Source: NCI Genomic Data Commons file 41cffed9-7e85-4592-86df-bf0d57f69031 (TCGA-06-0209.93A70661-A507-4B57-BEE6-B9BF201F31C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).